Somatic mutation profile of tumor specimen TCGA-CJ-5686-01A (aliquot TCGA-CJ-5686-01A-11D-1669-08) from TCGA case TCGA-CJ-5686, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.8 years (21,836 days).
Specimen TCGA-CJ-5686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b39c3ff9-8db8-4d73-83b1-36da6c43c5a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5686-11A (Solid Tissue Normal), aliquot TCGA-CJ-5686-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb7cc2e6-ecb9-457a-9813-aed13342c73b

The open-access MAF lists 66 somatic variants for this specimen: 50 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 15, Frame Shift Del 7, Nonsense Mutation 5, Splice Site 2, Frame Shift Ins 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK2 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV64491778; called by muse, mutect2, varscan2
- ANKMY2 | c.476A>G p.K159R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV61011398; called by muse, mutect2, varscan2
- ASAP2 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs753245120, COSV55629617; called by muse, mutect2, varscan2
- ATG7 | c.412-1G>T p.X138_splice | Splice Site (SNP) | VAF 10/55 reads (18%) | catalogued as COSV61611831; called by muse, mutect2, varscan2
- ATM | c.7255A>T p.R2419* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV53736068, COSV53774959; called by muse, mutect2, varscan2
- BMP1 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as COSV59244136; called by muse, mutect2, varscan2
- BRWD3 | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64746261; called by muse, mutect2, varscan2
- C8orf34 | c.1322C>G p.S441* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV57400749, COSV57402183; called by muse, mutect2, varscan2
- CCDC82 | c.1330T>C p.Y444H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53592159, COSV53592808; called by muse, mutect2, varscan2
- CDC45 | c.52A>T p.R18W | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54244444; called by muse, mutect2, varscan2
- CENPF | c.5978C>G p.S1993C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV65273869; called by muse, mutect2, varscan2
- DBN1 | c.477G>C p.V159= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as COSV52788712; called by muse, mutect2, varscan2
- DDX31 | c.2518G>C p.G840R | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.193); catalogued as COSV55037340; called by muse, mutect2, varscan2
- DIPK2A | c.101C>A p.S34* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV59856713, COSV59856830; called by muse, mutect2
- DNAH8 | c.12334G>A p.G4112R | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769556700, COSV59436429; called by muse, mutect2, varscan2
- EGLN2 | c.142T>C p.Y48H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58279644; called by mutect2, varscan2
- EMILIN1 | c.1793G>C p.G598A | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.878); catalogued as COSV53154123; called by muse, mutect2, varscan2
- EXTL3 | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV55037523; called by muse, mutect2, varscan2
- FGF14 | c.155A>T p.H52L | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV65939940; called by muse, mutect2, varscan2
- GPR45 | c.1076C>A p.P359Q | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51523335; called by muse, mutect2, varscan2
- GTSE1 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71889003; called by muse, mutect2, varscan2
- HAUS8 | c.560A>C p.K187T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV53725786; called by muse, mutect2, varscan2
- HECTD3 | c.1406G>T p.S469I | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as COSV55799718; called by muse, mutect2, varscan2
- HERPUD2 | c.1060-1G>A p.X354_splice | Splice Site (SNP) | VAF 36/157 reads (23%) | catalogued as COSV60944569, COSV60947565; called by muse, mutect2, varscan2
- IGSF10 | c.7712C>T p.S2571L | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56374607; called by muse, mutect2, varscan2
- INHBA | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54220629, COSV54222462; called by muse, mutect2, varscan2
- LRRN4CL | c.520G>C p.G174R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54015179, COSV54015389; called by muse, mutect2, varscan2
- OSBPL6 | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs756810077, COSV51914797; called by muse, mutect2
- PCSK6 | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59339703; called by muse, mutect2, varscan2
- PILRB | c.212G>A p.W71* | Nonsense Mutation (SNP) | VAF 27/134 reads (20%) | catalogued as COSV100167009, COSV60333752; called by muse, mutect2, varscan2
- RHEB | c.146T>A p.V49E | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV51262754; called by muse, mutect2
- SACS | c.13203G>T p.W4401C | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66538101; called by muse, mutect2, varscan2
- SHOC1 | c.1770G>T p.Q590H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59499545; called by muse, mutect2, varscan2
- SLC25A25 | c.509T>A p.L170Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV66085946; called by muse, mutect2, varscan2
- SLC35A1 | c.310A>G p.M104V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV65779956; called by muse, mutect2, varscan2
- SPHKAP | c.2791G>T p.E931* | Nonsense Mutation (SNP) | VAF 44/227 reads (19%) | catalogued as COSV60874257, COSV60882644; called by muse, mutect2, varscan2
- SUGP2 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); catalogued as rs373174595; called by muse, mutect2, varscan2
- TDRD6 | c.1774C>G p.Q592E | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV60174876; called by muse, mutect2, varscan2
- THBS4 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV63468787; called by muse, mutect2, varscan2
- UVSSA | c.943A>C p.K315Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV66229612; called by muse, mutect2, varscan2
- VHL | c.513del p.K171Nfs*31 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as COSV56545512, COSV56547521; called by mutect2, pindel, varscan2
- ZNF808 | c.2324G>T p.W775L | Missense Mutation (SNP) | VAF 53/291 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV63119327; called by muse, mutect2, varscan2
- CSDE1 | c.712_718del p.G238Kfs*28 (on ENST00000358528 / NM_001007553.3; = p.G207Kfs*28 on NM_007158.6) | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- IRS4 | c.3317_3320del p.D1106Afs*22 | Frame Shift Del (DEL) | VAF 38/224 reads (17%) | called by pindel, varscan2
- NRAP | c.3182del p.S1061Mfs*12 (on ENST00000359988 / NM_001322945.2; = p.S1026Mfs*12 on NM_006175.4) | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel
- SPG7 | c.1655dup p.S553Efs*16 (on ENST00000268704; = p.S560Efs*16 on NM_003119.4) | Frame Shift Ins (INS) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- TKFC | c.33del p.G12Afs*56 | Frame Shift Del (DEL) | VAF 20/133 reads (15%) | called by mutect2, pindel, varscan2
- TSPYL1 | c.291del p.Q98Rfs*17 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- WNT8A | c.602_603delinsA p.F201Yfs*8 | Frame Shift Del (DEL) | VAF 17/95 reads (18%) | called by pindel, varscan2*
- ZNF318 | c.4475dup p.P1493Sfs*2 | Frame Shift Ins (INS) | VAF 11/82 reads (13%) | called by mutect2, pindel, varscan2
- AAAS | c.1134G>T p.V378= | Silent (SNP) | VAF 23/166 reads (14%) | catalogued as COSV52932592; called by muse, mutect2, varscan2
- CDK3 | c.297C>A p.L99= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV56909354; called by muse, mutect2
- EEF1A1 | c.876C>A p.V292= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs200820708, COSV58549256; called by muse, mutect2, varscan2
- FERMT2 | c.324T>C p.Y108= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as COSV58406197; called by muse, mutect2, varscan2
- FZD10 | c.837C>T p.I279= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV57472900; called by muse, mutect2, varscan2
- PITPNM3 | c.531C>T p.L177= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs374847640, COSV52594590; called by muse, mutect2, varscan2
- RAB23 | c.69A>T p.S23= | Silent (SNP) | VAF 34/229 reads (15%) | catalogued as COSV58097606; called by muse, mutect2, varscan2
- RAPGEF3 | c.831G>A p.G277= (on ENST00000389212; = p.G235= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/138 reads (17%) | catalogued as COSV50200914; called by muse, mutect2, varscan2
- RYR1 | c.9765G>T p.G3255= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV62093931, COSV62101633; called by muse, mutect2, varscan2
- TAF1 | c.1506T>C p.S502= (on ENST00000373790 / NM_138923.4; = p.S523= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV52110519; called by muse, mutect2, varscan2
- TAP2 | c.112C>T p.L38= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV66487693; called by muse, mutect2, varscan2
- TBPL2 | c.912C>T p.P304= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV55972243; called by muse, mutect2, varscan2
- TMEM68 | c.936A>G p.P312= (on ENST00000434581 / NM_001363177.1; = p.P245= on NM_152417.3) | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV58170417; called by muse, mutect2, varscan2
- VPS13D | c.1452G>T p.S484= | Silent (SNP) | VAF 15/202 reads (7%) | catalogued as COSV62527671; called by muse, mutect2
- ZFPM2 | c.753T>C p.P251= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1219245719, COSV65873049; called by muse, mutect2, varscan2
- AKT2 | c.*244T>C | 3'UTR (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100251447; called by muse, mutect2
